Somatic mutation profile of tumor specimen MMRF_1155_2_BM_CD138pos (aliquot MMRF_1155_2_BM_CD138pos_T1_KHS5U_L16524) from MMRF case MMRF_1155, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.1 years (23,036 days).
Specimen MMRF_1155_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b65504b7-f3e8-4809-ad60-859ea508ce7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1155_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1155_1_PB_Whole_C2_KBS5U_L05768; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/219ecf45-5318-4933-a207-e90013db6cae

The open-access MAF lists 248 somatic variants for this specimen: 88 protein-altering or splice-affecting, 39 silent, 121 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 75, Missense Mutation 70, Silent 39, Intron 31, 3'Flank 6, Frame Shift Del 5, Nonsense Mutation 4, 5'Flank 4, Splice Site 4, Frame Shift Ins 3, 5'UTR 3, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 58/270 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ATP6V1B1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 82/174 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1553419944; called by muse, mutect2, varscan2
- C19orf57 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 16/265 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.865); catalogued as COSV60968384; called by muse, mutect2
- CCKAR | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 16/455 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.649); catalogued as COSV99810381; called by muse, mutect2
- CD177 | c.760+1G>C p.X254_splice | Splice Site (SNP) | VAF 17/86 reads (20%) | catalogued as COSV65122489; called by muse, mutect2
- CNTNAP1 | c.1642_1643del p.M548Vfs*2 | Frame Shift Del (DEL) | VAF 74/206 reads (36%) | catalogued as rs1262146130; called by mutect2, pindel, varscan2
- DGKE | c.1154A>G p.N385S | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs145980200; called by muse, mutect2, varscan2
- DMC1 | c.858dup p.P287Tfs*31 | Frame Shift Ins (INS) | VAF 102/271 reads (38%) | catalogued as rs1359383682; called by mutect2, pindel, varscan2
- EMD | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs782455914, COSV63962229; called by muse, mutect2, varscan2
- ETFDH | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 89/234 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM110987, COSV57014659; called by muse, mutect2, varscan2
- FGD5 | c.1334del p.G445Efs*18 | Frame Shift Del (DEL) | VAF 77/271 reads (28%) | catalogued as COSV53250036; called by mutect2, pindel, varscan2
- GPR32 | c.585C>A p.F195L | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV54515844; called by muse, mutect2, varscan2
- HS3ST3A1 | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as rs1013190360; called by mutect2, varscan2
- IGHD6-19 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 178/184 reads (97%) | catalogued as rs547049153; called by muse, mutect2, varscan2
- LAMC3 | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1489032372; called by muse, mutect2, varscan2
- LCNL1 | c.343del p.R115Afs*94 | Frame Shift Del (DEL) | VAF 30/212 reads (14%) | catalogued as rs1314445856; called by mutect2, pindel, varscan2
- MAP6 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs777211062; called by muse, mutect2, varscan2
- NOX5 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 33/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52992252; called by muse, mutect2
- OTOGL | c.6083T>C p.L2028P (on ENST00000547103; = p.L2019P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.723); catalogued as COSV54015083; called by muse, mutect2, varscan2
- RELN | c.3987G>A p.M1329I | Missense Mutation (SNP) | VAF 136/327 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1562908501, COSV59040768; called by muse, mutect2, varscan2
- RMND5A | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.216); catalogued as rs1435578822; called by muse, mutect2, varscan2
- SDK1 | c.4676T>C p.I1559T | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as rs763847417; called by muse, mutect2, varscan2
- SHANK1 | c.262C>T p.L88F | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV53252050; called by muse, mutect2, varscan2
- SLC38A6 | c.558del p.I188* | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | catalogued as rs1412576119; called by mutect2, pindel, varscan2
- TRIML1 | c.371G>C p.R124T | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV60193419; called by muse, mutect2, varscan2
- TTYH1 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 117/215 reads (54%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs771847339; called by muse, mutect2, varscan2
- UMOD | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 83/141 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.404); catalogued as rs763212690, COSV56773531; called by muse, mutect2, varscan2
- ZNF462 | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 330/518 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52953226; called by muse, mutect2, varscan2
- AGBL3 | c.2510del p.K837Rfs*11 | Frame Shift Del (DEL) | VAF 28/172 reads (16%) | called by mutect2, pindel, varscan2
- AJM1 | c.2776G>T p.E926* | Nonsense Mutation (SNP) | VAF 38/500 reads (8%) | called by muse, mutect2
- ANK3 | c.11419G>T p.V3807F | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- ANKRD31 | c.1618G>C p.E540Q | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP13A5 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 137/214 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- CACTIN | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CELSR3 | c.1048C>G p.Q350E | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.036); called by muse, mutect2
- CIT | c.3353C>T p.S1118F | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- CMYA5 | c.93G>T p.E31D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- COL16A1 | c.1727G>T p.G576V | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- CP | c.2065C>G p.P689A | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- CTXN3 | c.145T>G p.F49V | Missense Mutation (SNP) | VAF 90/187 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CWH43 | c.1157dup p.R387Qfs*4 | Frame Shift Ins (INS) | VAF 39/76 reads (51%) | called by mutect2, pindel, varscan2
- CXorf56 | c.273G>C p.Q91H (on ENST00000536133 / NM_001170570.2; = p.Q105H on NM_022101.4) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- CYP21A2 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DDX42 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH10 | c.9063G>A p.M3021I (on ENST00000409039; = p.M2960I on NM_207437.3) | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2
- DNAH5 | c.8000G>A p.W2667* | Nonsense Mutation (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- DNAH8 | c.8272C>A p.P2758T | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DNAH8 | c.9895G>C p.G3299R | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DOK7 | c.521G>T p.R174M | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DST | c.6766C>T p.P2256S | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ELMO1 | c.269A>T p.E90V | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.119); called by muse, mutect2
- EXOSC10 | c.236G>T p.R79M | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FLNB | c.1345+1G>T p.X449_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- GBA | c.1306T>G p.F436V | Missense Mutation (SNP) | VAF 145/308 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- GEMIN5 | c.2355A>C p.Q785H | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- GNAQ | c.482T>G p.L161R | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRHL3 | c.761A>T p.N254I (on ENST00000350501 / NM_198174.3; = p.N259I on NM_021180.3) | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRID2 | c.2360+2T>A p.X787_splice | Splice Site (SNP) | VAF 36/269 reads (13%) | called by muse, mutect2, varscan2
- GRM5 | c.2966G>A p.G989E (on ENST00000305447 / NM_001143831.2; = p.G957E on NM_000842.4) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HUWE1 | c.8006T>C p.V2669A | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.857); called by mutect2, varscan2
- IGHV3-13 | c.186dup p.G63Rfs*13 | Frame Shift Ins (INS) | VAF 18/121 reads (15%) | called by mutect2, pindel, varscan2
- INTS4 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 124/413 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- JAK2 | c.2092A>T p.S698C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRP6 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MACF1 | c.4950G>C p.E1650D | Missense Mutation (SNP) | VAF 36/319 reads (11%) | called by muse, mutect2, varscan2
- MAGED1 | c.1008_1025del p.A337_V342del | In Frame Del (DEL) | VAF 84/110 reads (76%) | called by mutect2, varscan2
- MAX | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 108/119 reads (91%) | called by muse, mutect2, varscan2
- MMRN1 | c.3541A>C p.I1181L | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MRPL10 | c.119T>G p.M40R | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MUC16 | c.19853A>G p.K6618R | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NPPB | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 214/321 reads (67%) | called by muse, mutect2, varscan2
- NSD2 | c.2876A>T p.K959I | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- NTRK3 | c.1985A>G p.Q662R | Missense Mutation (SNP) | VAF 70/312 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NUSAP1 | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2
- PALLD | c.439A>C p.T147P | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIP5K1A | c.525C>A p.S175R (on ENST00000368888 / NM_001135638.2; = p.S162R on NM_003557.3) | Missense Mutation (SNP) | VAF 74/160 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- PIPOX | c.683A>C p.Y228S | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLA2G4D | c.953A>C p.D318A | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2
- PLEKHA5 | c.2401-8_2401-2delinsG p.X801_splice | Splice Site (DEL) | VAF 13/58 reads (22%) | called by pindel, varscan2*
- PP2D1 | c.1379T>A p.V460D | Missense Mutation (SNP) | VAF 48/335 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PREX2 | c.1037C>G p.P346R | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- RSL24D1 | c.33_35dup p.P12dup | In Frame Ins (INS) | VAF 50/599 reads (8%) | called by mutect2, pindel
- SH3TC2 | c.2726T>C p.L909P | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SLC4A2 | c.2182G>C p.G728R | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- TMEM245 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- TRAF3IP3 | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2
- TTLL3 | c.1756G>C p.V586L | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- VPS13A | c.6744T>G p.F2248L | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGAP3 | c.873C>T p.G291= (on ENST00000622464; = p.G327= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as rs544517501; called by muse, mutect2, varscan2
- ALDH1L1 | c.1059G>A p.A353= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as rs780671610, COSV99856559; called by muse, mutect2, varscan2
- ALG2 | c.1248A>G p.V416= | Silent (SNP) | VAF 120/353 reads (34%) | called by muse, mutect2, varscan2
- C9orf50 | c.1245G>A p.K415= | Silent (SNP) | VAF 27/190 reads (14%) | called by muse, mutect2, varscan2
- CLEC4G | c.255G>A p.K85= | Silent (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
- COL15A1 | c.3966C>T p.V1322= | Silent (SNP) | VAF 50/298 reads (17%) | catalogued as COSV66641562; called by muse, mutect2, varscan2
- CRX | c.726G>T p.V242= | Silent (SNP) | VAF 81/180 reads (45%) | catalogued as COSV55758187; called by muse, mutect2, varscan2
- CSRNP3 | c.255C>G p.P85= | Silent (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- DDOST | c.741C>G p.L247= (on ENST00000415136; = p.L230= on NM_005216.5) | Silent (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2
- DDX51 | c.360A>G p.P120= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs749812289, COSV57957198; called by muse, varscan2
- DNAH7 | c.10653C>T p.I3551= | Silent (SNP) | VAF 88/225 reads (39%) | catalogued as COSV100415299; called by muse, mutect2, varscan2
- DTX3 | c.711C>T p.T237= | Silent (SNP) | VAF 46/212 reads (22%) | called by muse, mutect2, varscan2
- DUXA | c.318C>G p.T106= | Silent (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- GATAD2A | c.1596G>T p.R532= | Silent (SNP) | VAF 60/226 reads (27%) | called by muse, mutect2, varscan2
- GRAP2 | c.912C>T p.S304= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as rs1351686358; called by muse, mutect2, varscan2
- HCRTR1 | c.1137C>T p.G379= | Silent (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- IGHD6-19 | c.15C>T p.G5= | Silent (SNP) | VAF 177/183 reads (97%) | called by muse, mutect2, varscan2
- IQGAP2 | c.3942G>A p.Q1314= | Silent (SNP) | VAF 66/340 reads (19%) | called by muse, mutect2, varscan2
- KAT5 | c.675C>T p.I225= | Silent (SNP) | VAF 137/428 reads (32%) | catalogued as rs778427253; called by muse, mutect2, varscan2
- LY75 | c.4473G>A p.L1491= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as rs746213981; called by muse, mutect2, varscan2
- LYSMD4 | c.582C>T p.D194= (on ENST00000409796 / NM_001284417.2; = p.D195= on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/386 reads (8%) | catalogued as rs1386332270; called by muse, mutect2
- MDH1B | c.1008A>G p.G336= | Silent (SNP) | VAF 48/109 reads (44%) | called by muse, mutect2, varscan2
- MUC16 | c.6483T>G p.S2161= | Silent (SNP) | VAF 89/162 reads (55%) | called by muse, mutect2, varscan2
- NPPB | c.108G>A p.S36= | Silent (SNP) | VAF 211/317 reads (67%) | catalogued as rs1039076006, COSV100916106; called by muse, mutect2, varscan2
- OR4D6 | c.744T>C p.T248= | Silent (SNP) | VAF 61/218 reads (28%) | called by muse, mutect2, varscan2
- PCLO | c.1845C>A p.T615= | Silent (SNP) | VAF 95/216 reads (44%) | catalogued as COSV61639685; called by muse, mutect2, varscan2
- PEX11G | c.675C>T p.S225= | Silent (SNP) | VAF 52/195 reads (27%) | called by muse, mutect2, varscan2
- PLXND1 | c.2862C>T p.A954= | Silent (SNP) | VAF 46/248 reads (19%) | catalogued as rs1357833527; called by muse, mutect2, varscan2
- PTBP3 | c.84A>T p.G28= | Silent (SNP) | VAF 116/394 reads (29%) | called by muse, mutect2, varscan2
- RAB17 | c.273C>A p.A91= | Silent (SNP) | VAF 20/124 reads (16%) | called by muse, mutect2, varscan2
- RBM15B | c.2655C>T p.I885= | Silent (SNP) | VAF 154/522 reads (30%) | catalogued as rs201500904; called by muse, mutect2, varscan2
- SCYL1 | c.1797C>G p.P599= | Silent (SNP) | VAF 37/328 reads (11%) | called by muse, mutect2, varscan2
- SLC45A1 | c.237C>T p.H79= | Silent (SNP) | VAF 103/314 reads (33%) | catalogued as rs779076880; called by muse, mutect2, varscan2
- SPATA7 | c.363C>T p.T121= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99248272; called by muse, mutect2
- STAP2 | c.1095C>T p.G365= (on ENST00000594605 / NM_001013841.2; = p.G411= on NM_017720.3) | Silent (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- WNT10B | c.708C>G p.R236= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- ZCCHC2 | c.2805G>A p.V935= | Silent (SNP) | VAF 16/233 reads (7%) | called by muse, mutect2
- ZNF256 | c.258C>T p.P86= | Silent (SNP) | VAF 34/178 reads (19%) | called by muse, mutect2, varscan2
- ZNF618 | c.1938C>T p.S646= (on ENST00000374126 / NM_001318042.2; = p.S553= on NM_133374.2) | Silent (SNP) | VAF 80/262 reads (31%) | catalogued as rs376683289; called by muse, mutect2, varscan2
- ACTA2 | c.991-156A>G | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- AFAP1 | c.*2995A>G | 3'UTR (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- AFAP1 | c.*2469C>T | 3'UTR (SNP) | VAF 31/147 reads (21%) | called by muse, mutect2, varscan2
- ANKRD44 | c.*54A>G | 3'UTR (SNP) | VAF 4/56 reads (7%) | catalogued as rs994117927; called by muse, mutect2
- AP3B2 | c.2081-40C>T | Intron (SNP) | VAF 21/227 reads (9%) | called by muse, mutect2
- AR | c.*2261C>T | 3'UTR (SNP) | VAF 22/23 reads (96%) | catalogued as rs1569317253; called by muse, mutect2, varscan2
- ARHGEF39 | c.*597G>A | 3'UTR (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- ARID5B | c.*1071C>G | 3'UTR (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- ATP10D | c.*816C>G | 3'UTR (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- BCHE | c.*275T>G | 3'UTR (SNP) | VAF 12/125 reads (10%) | catalogued as rs1461392819; called by muse, mutect2, varscan2
- BEND7 | c.1081+2149G>C | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- C10orf90 | c.*822T>C | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2
- C1QTNF12 | c.178-55C>T | Intron (SNP) | VAF 39/59 reads (66%) | called by muse, mutect2, varscan2
- C1orf158 | c.*1461T>A | 3'UTR (SNP) | VAF 84/286 reads (29%) | called by muse, varscan2
- C5orf38 | c.*348T>C | 3'UTR (SNP) | VAF 138/280 reads (49%) | called by muse, mutect2, varscan2
- C6orf62 | c.*312A>T | 3'UTR (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- CACNA1E | c.*8350A>T | 3'UTR (SNP) | VAF 4/52 reads (8%) | catalogued as rs1010414045; called by muse, mutect2
- CALD1 | c.71+21del | Intron (DEL) | VAF 48/273 reads (18%) | called by mutect2, pindel, varscan2
- CARNMT1 | c.*125A>G | 3'UTR (SNP) | VAF 119/370 reads (32%) | called by muse, mutect2, varscan2
- CBX5 | c.*1538G>A | 3'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- CCSAP | c.*1762G>A | 3'UTR (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2, varscan2
- CHFR | chr12:132840334 G>C | 3'Flank (SNP) | VAF 6/16 reads (38%) | catalogued as rs542673371; called by muse, varscan2
- CHRNB2 | c.*1391C>G | 3'UTR (SNP) | VAF 13/121 reads (11%) | called by muse, mutect2, varscan2
- CLSTN1 | c.*528T>G | 3'UTR (SNP) | VAF 72/122 reads (59%) | called by muse, mutect2, varscan2
- CPE | c.*115T>C | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- CREB1 | c.*2172A>C | 3'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- CXCR2 | c.*22C>A | 3'UTR (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- DHCR7 | c.*293G>T | 3'UTR (SNP) | VAF 31/227 reads (14%) | called by muse, mutect2, varscan2
- DLGAP1 | c.957+4828A>G | Intron (SNP) | VAF 94/195 reads (48%) | called by muse, varscan2
- DNMT3A | c.1014+72G>C | Intron (SNP) | VAF 36/84 reads (43%) | catalogued as COSV104391749, COSV53038292; called by muse, mutect2, varscan2
- DPP4 | c.7-84T>G | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- DRD3 | chr3:114128560 G>A | 3'Flank (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- DUOX2 | c.3184+61G>C | Intron (SNP) | VAF 36/136 reads (26%) | called by muse, mutect2, varscan2
- EFCAB1 | c.*463C>A | 3'UTR (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- EIF3J | c.*308G>C | 3'UTR (SNP) | VAF 119/267 reads (45%) | catalogued as COSV56000340; called by muse, mutect2, varscan2
- ELF5 | c.385+266C>A | Intron (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- ENAH | c.*1847del | 3'UTR (DEL) | VAF 40/70 reads (57%) | catalogued as rs898565355; called by mutect2, varscan2
- EXOC3 | chr5:441841 T>G | 5'Flank (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- FAS | c.*1117G>A | 3'UTR (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- FBRS | c.214-59G>C | Intron (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2
- FIGN | c.*1303del | 3'UTR (DEL) | VAF 30/74 reads (41%) | called by mutect2, pindel, varscan2
- FLRT2 | c.*255G>C | 3'UTR (SNP) | VAF 11/25 reads (44%) | catalogued as COSV100420992; called by muse, mutect2, varscan2
- FYTTD1 | c.*30G>A | 3'UTR (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- GAB1 | chr4:143474078 C>G | 3'Flank (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- GABRB3 | c.241-7531G>T | Intron (SNP) | VAF 61/253 reads (24%) | called by muse, mutect2, varscan2
- GABRG1 | c.*5089A>G | 3'UTR (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2, varscan2
- GFRA3 | c.*200G>T | 3'UTR (SNP) | VAF 6/69 reads (9%) | catalogued as rs775646123; called by muse, mutect2
- GLRA3 | c.*3685T>C | 3'UTR (SNP) | VAF 44/84 reads (52%) | called by muse, mutect2, varscan2
- GPR107 | c.*2625C>G | 3'UTR (SNP) | VAF 20/168 reads (12%) | called by muse, varscan2
- GPR55 | chr2:230907568 T>C | 3'Flank (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- GRM1 | c.*976C>T | 3'UTR (SNP) | VAF 43/85 reads (51%) | called by muse, mutect2, varscan2
- H3C11 | c.*6C>G | 3'UTR (SNP) | VAF 159/391 reads (41%) | called by muse, mutect2, varscan2
- HES2 | c.*765G>A | 3'UTR (SNP) | VAF 14/310 reads (5%) | called by muse, mutect2
- HSPA5 | c.-140T>C | 5'UTR (SNP) | VAF 92/276 reads (33%) | called by muse, mutect2
- IFIT5 | c.*2270C>A | 3'UTR (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- IGSF11 | c.*552G>T | 3'UTR (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- IKBKE | c.1733+303G>A | Intron (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- KCNH6 | c.1501+61T>C | Intron (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- LARP4B | c.*367dup | 3'UTR (INS) | VAF 5/52 reads (10%) | catalogued as rs1225525670; called by mutect2*, pindel, varscan2*
- LCE1A | c.*167T>G | 3'UTR (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- LRRC7 | c.*958A>T | 3'UTR (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- LSM1 | chr8:38176561 G>A | 5'Flank (SNP) | VAF 48/51 reads (94%) | called by muse, mutect2, varscan2
- MAP4 | c.292+3950T>A | Intron (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- MARF1 | c.4627-201C>A | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- MAT1A | c.*1539C>T | 3'UTR (SNP) | VAF 25/150 reads (17%) | called by muse, mutect2, varscan2
- MED19 | c.*199T>G | 3'UTR (SNP) | VAF 65/107 reads (61%) | called by muse, mutect2, varscan2
- METTL9 | c.*186C>A | 3'UTR (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- MIR515-2 | n.69C>A | RNA (SNP) | VAF 25/138 reads (18%) | called by muse, mutect2, varscan2
- MOG | c.730+78G>A | Intron (SNP) | VAF 64/116 reads (55%) | catalogued as rs774294135; called by muse, mutect2, varscan2
- NFAT5 | c.-95C>A | 5'UTR (SNP) | VAF 59/74 reads (80%) | called by muse, mutect2, varscan2
- NFKBID | c.153-34G>A | Intron (SNP) | VAF 96/226 reads (42%) | catalogued as rs752418290; called by muse, mutect2, varscan2
- NRDC | chr1:51878894 del GACT | 5'Flank (DEL) | VAF 150/265 reads (57%) | called by mutect2, pindel, varscan2
- OSBPL1A | c.282+15A>T | Intron (SNP) | VAF 109/234 reads (47%) | called by muse, mutect2, varscan2
- PARVA | c.*1327C>A | 3'UTR (SNP) | VAF 36/145 reads (25%) | called by muse, mutect2, varscan2
- PDGFRL | c.*45T>C | 3'UTR (SNP) | VAF 167/334 reads (50%) | called by muse, mutect2, varscan2
- PITX2 | c.390+455G>T | Intron (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- PLIN5 | c.*50C>A | 3'UTR (SNP) | VAF 43/106 reads (41%) | catalogued as rs779628821; called by muse, mutect2, varscan2
- PPP1CC | c.883-247C>A | Intron (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- PRDM10 | c.*1830A>T | 3'UTR (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*7155C>A | 3'UTR (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- PRND | chr20:4732436 C>G | 3'Flank (SNP) | VAF 6/159 reads (4%) | called by muse, mutect2
- PRPF18 | c.66+4694G>T | Intron (SNP) | VAF 134/308 reads (44%) | called by muse, mutect2
- PTEN | c.*2717A>C | 3'UTR (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.724+36G>A | Intron (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2
- PTP4A1 | c.*2060A>G | 3'UTR (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- RAB3B | c.*5018C>G | 3'UTR (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- RAB40B | c.*184G>T | 3'UTR (SNP) | VAF 74/142 reads (52%) | called by muse, mutect2, varscan2
- RAPGEF1 | c.*2128C>T | 3'UTR (SNP) | VAF 76/257 reads (30%) | called by muse, mutect2, varscan2
- RASD1 | c.*273G>A | 3'UTR (SNP) | VAF 37/181 reads (20%) | called by muse, mutect2, varscan2
- RASGRF2 | c.*482C>A | 3'UTR (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- RASGRP1 | chr15:38565541 G>A | 5'Flank (SNP) | VAF 13/163 reads (8%) | called by muse, mutect2
- RNF111 | chr15:59096507 C>T | 3'Flank (SNP) | VAF 28/191 reads (15%) | called by muse, mutect2, varscan2
- RNF24 | c.*1032A>G | 3'UTR (SNP) | VAF 28/52 reads (54%) | catalogued as rs566643183; called by muse, mutect2, varscan2
- SLC1A4 | c.*124G>A | 3'UTR (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- SLC25A18 | c.730+72A>C | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- SLC25A31 | c.*418A>C | 3'UTR (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- SLC37A1 | c.-120C>A | 5'UTR (SNP) | VAF 63/187 reads (34%) | called by muse, mutect2, varscan2
- SLC52A2 | c.1002-38G>T | Intron (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- SRBD1 | c.*540G>T | 3'UTR (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- SRPK1 | c.1691-24T>C | Intron (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- SRRM4 | c.*3501C>G | 3'UTR (SNP) | VAF 6/16 reads (38%) | catalogued as rs1052345039; called by muse, varscan2
- ST3GAL1 | c.*2129T>G | 3'UTR (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- STAC | c.*1383T>A | 3'UTR (SNP) | VAF 20/90 reads (22%) | catalogued as COSV56211634; called by muse, mutect2, varscan2
- STK40 | c.*992G>A | 3'UTR (SNP) | VAF 48/406 reads (12%) | called by muse, mutect2, varscan2
- TAGLN2 | c.-29+859T>C | Intron (SNP) | VAF 54/115 reads (47%) | called by muse, mutect2, varscan2
- TBC1D12 | c.*1361T>G | 3'UTR (SNP) | VAF 51/99 reads (52%) | called by muse, mutect2, varscan2
- THBS3 | c.2074+24G>A | Intron (SNP) | VAF 16/29 reads (55%) | catalogued as rs746326628; called by muse, mutect2, varscan2
- TMEM260 | c.*1191G>A | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- TMX4 | c.*307G>A | 3'UTR (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- TP53I11 | c.238-46C>T | Intron (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- TRPA1 | c.*335C>T | 3'UTR (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- TRPV3 | c.*2263G>T | 3'UTR (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- TSPAN31 | c.558+9C>G | Intron (SNP) | VAF 232/237 reads (98%) | called by muse, mutect2, varscan2
- TSPAN33 | c.*935C>T | 3'UTR (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- UTRN | c.7479+6221T>C | Intron (SNP) | VAF 99/242 reads (41%) | called by muse, mutect2, varscan2
- Unknown | chr7:55707178 A>T | IGR (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- VAMP4 | c.*739C>G | 3'UTR (SNP) | VAF 32/133 reads (24%) | called by muse, mutect2, varscan2
- VILL | c.*26_*27del | 3'UTR (DEL) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- ZNF207 | c.*9766G>A | 3'UTR (SNP) | VAF 18/78 reads (23%) | catalogued as rs1370696373, COSV67142588; called by muse, mutect2, varscan2
- ZNF704 | c.*1937C>T | 3'UTR (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- ZSCAN25 | c.*2030G>C | 3'UTR (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
